MMRF case MMRF_2690 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ef8c4403-8f4a-4cdc-97bd-9b04a990a19e

Demographics
Sex at birth: male; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.9 years (18,953 days); ISS stage: II; Days to last known disease status: 467 days (1.3 years); Days to last follow up: 467 days (1.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -5, day 467.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.47 mmol/L.
- Absolute Neutrophil 4.73 ×10⁹/L.
- Creatinine 89.3 µmol/L.
- Lactate Dehydrogenase 3.02 µkat/L.
- Hemoglobin 7.25 mmol/L.
- Albumin 46 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 95 mg/dL.
- Beta 2 Microglobulin 3.9 µg/mL.
- Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL.
- Platelets 164 ×10⁹/L.

Other clinical attributes
- Day -5: Weight: 67 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2690_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2690_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
